Somatic mutation profile of tumor specimen TCGA-2Z-A9J5-01A (aliquot TCGA-2Z-A9J5-01A-21D-A382-10) from TCGA case TCGA-2Z-A9J5, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 80.2 years (29,275 days).
Specimen TCGA-2Z-A9J5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6ad8a3a-e9c8-47bf-b728-0243a041ac5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9J5-10A (Blood Derived Normal), aliquot TCGA-2Z-A9J5-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f981408e-d875-4a8c-9756-6b8447f5af46

The open-access MAF lists 102 somatic variants for this specimen: 80 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 20, Frame Shift Del 10, Nonsense Mutation 5, Frame Shift Ins 2, Splice Site 2, Translation Start Site 2, Intron 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF2 | c.1292C>G p.P431R | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99734541; called by muse, mutect2, varscan2
- ADGRB3 | c.975C>G p.H325Q | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.506); catalogued as COSV101000936; called by muse, mutect2, varscan2
- AGL | c.1043T>A p.V348E | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV99649420; called by muse, mutect2, varscan2
- ALKBH5 | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as rs1332435764, COSV101213277; called by muse, mutect2, varscan2
- ANO3 | c.2243T>C p.L748P | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99883474; called by muse, mutect2, varscan2
- APC | c.2876C>A p.S959Y | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs757526267, COSV99968396; called by muse, mutect2, varscan2
- ARHGAP20 | c.1981A>G p.N661D | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99504419; called by muse, mutect2, varscan2
- ARID1A | c.1345C>T p.Q449* | Nonsense Mutation (SNP) | VAF 63/228 reads (28%) | catalogued as COSV61388110; called by muse, mutect2, varscan2
- ATP5F1C | c.565A>T p.K189* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100184343; called by muse, mutect2, varscan2
- BIRC6 | c.1429C>A p.L477M | Missense Mutation (SNP) | VAF 115/260 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.945); catalogued as COSV101428403; called by muse, mutect2, varscan2
- BIRC6 | c.9856C>T p.R3286W | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372922939; called by muse, varscan2
- CARD11 | c.1262T>A p.M421K | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV101210759; called by muse, mutect2, varscan2
- CCDC183 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100273446; called by muse, mutect2, varscan2
- CCDC7 | c.530T>A p.L177H | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.977); catalogued as COSV99511670; called by muse, mutect2, varscan2
- CHMP2B | c.346A>G p.M116V | Missense Mutation (SNP) | VAF 133/641 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99773496; called by muse, mutect2, varscan2
- CNOT4 | c.1522A>G p.I508V (on ENST00000315544 / NM_001190848.1; = p.I505V on NM_013316.4) | Missense Mutation (SNP) | VAF 96/198 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV100211765; called by muse, mutect2, varscan2
- COL22A1 | c.1588G>A p.G530S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs951433699, COSV57331188; called by muse, mutect2
- COL22A1 | c.1587G>T p.K529N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100278934, COSV57324822; called by muse, mutect2
- CPT1B | c.1796A>G p.E599G | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100376715; called by muse, mutect2, varscan2
- CR1 | c.4553C>T p.S1518F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.857); catalogued as COSV100887684; called by muse, mutect2, varscan2
- DAZAP1 | c.1217G>C p.R406P | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV99245321; called by muse, mutect2, varscan2
- DDIAS | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1238794511, COSV61272219; called by muse, mutect2, varscan2
- DHX9 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV100841439; called by muse, mutect2, varscan2
- EPHA3 | c.686del p.S229Ffs*57 | Frame Shift Del (DEL) | VAF 48/128 reads (38%) | catalogued as COSV100349524, COSV60706391; called by mutect2, pindel, varscan2
- EZH1 | c.1003A>G p.T335A | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV70551090; called by muse, mutect2, varscan2
- FOXD4L1 | c.1049G>A p.S350N | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as rs1284571007, COSV99380608; called by muse, mutect2, varscan2
- FRS2 | c.62T>G p.F21C | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100166130; called by muse, mutect2, varscan2
- GPR183 | c.898A>C p.N300H | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100854302; called by muse, mutect2, varscan2
- HERC2 | c.6913C>T p.Q2305* | Nonsense Mutation (SNP) | VAF 54/190 reads (28%) | catalogued as COSV99874632; called by muse, mutect2, varscan2
- HUWE1 | c.11869C>A p.R3957S | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV53338969, COSV99472842; called by muse, mutect2, varscan2
- IFI30 | c.455T>C p.F152S | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV101325326; called by muse, mutect2, varscan2
- JMJD1C | c.2745T>A p.D915E | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as COSV100550643; called by muse, mutect2, varscan2
- MUS81 | c.296A>T p.E99V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100354100; called by muse, mutect2, varscan2
- MYO1H | c.1641A>T p.K547N | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV100183681; called by muse, mutect2
- NFATC3 | c.884del p.P295Lfs*11 | Frame Shift Del (DEL) | VAF 38/105 reads (36%) | catalogued as COSV60476324; called by mutect2, pindel, varscan2
- NOL4L | c.282G>C p.K94N | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV100675635; called by muse, mutect2, varscan2
- NOTCH3 | c.2792G>A p.S931N | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99657657; called by muse, mutect2, varscan2
- OTULIN | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV99419824; called by muse, mutect2, varscan2
- PAMR1 | c.1222A>G p.T408A (on ENST00000619888 / NM_001001991.3; = p.T425A on NM_015430.4) | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs147274037; called by muse, mutect2, varscan2
- PCDHAC1 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV99166878; called by muse, mutect2, varscan2
- PLD5 | c.709G>T p.G237C (on ENST00000442594; = p.G175C on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100139194, COSV100139984, COSV59156719; called by muse, mutect2, varscan2
- PLXNA4 | c.5592C>A p.I1864= | Splice Region (SNP) | VAF 36/110 reads (33%) | catalogued as COSV100324962; called by muse, mutect2
- PPP1R15B | c.1154G>T p.C385F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as COSV100916347; called by muse, mutect2, varscan2
- PRAMEF1 | c.683T>G p.L228R | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100179814; called by muse, mutect2, varscan2
- PSMC2 | c.1144+1G>T p.X382_splice | Splice Site (SNP) | VAF 38/90 reads (42%) | catalogued as COSV99485363; called by muse, mutect2, varscan2
- RHCE | c.587A>G p.E196G | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.36); catalogued as COSV99604142; called by muse, mutect2, varscan2
- RHOBTB1 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100558533; called by muse, mutect2, varscan2
- RNF19A | c.1481T>C p.V494A | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.217); catalogued as COSV100347818; called by muse, mutect2, varscan2
- RPTN | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV100285563; called by muse, mutect2, varscan2
- SDCBP2 | c.328C>T p.H110Y (on ENST00000339987 / NM_001199784.1; = p.H25Y on NM_015685.5) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100378241; called by muse, mutect2, varscan2
- SEC23IP | c.1033T>A p.W345R | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100956903; called by muse, mutect2, varscan2
- SETX | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV56394740; called by muse, mutect2, varscan2
- SLC17A7 | c.435-1G>C p.X145_splice | Splice Site (SNP) | VAF 31/127 reads (24%) | catalogued as COSV99676904; called by muse, mutect2, varscan2
- SLC47A1 | c.736G>T p.G246* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV99565405; called by muse, mutect2, varscan2
- SNX29 | c.1688T>C p.L563P | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100029172; called by muse, mutect2, varscan2
- SOCS1 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.544); catalogued as COSV59661301; called by muse, mutect2, varscan2
- SPPL2A | c.854T>A p.M285K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99961669; called by muse, mutect2, varscan2
- SYNE2 | c.13619T>A p.L4540H | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100647937; called by muse, mutect2, varscan2
- TFAP4 | c.462G>C p.E154D | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99200070; called by muse, mutect2, varscan2
- TNPO3 | c.1274C>G p.S425C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.524); catalogued as COSV99603075; called by muse, mutect2, varscan2
- TOR1B | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 28/47 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV99400215; called by muse, mutect2, varscan2
- TSC22D1 | c.3139T>C p.S1047P (on ENST00000458659 / NM_183422.4; = p.S118P on NM_006022.4) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs772780188, COSV54925546; called by muse, mutect2, varscan2
- TTI2 | c.1055C>G p.P352R | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV100659749; called by muse, mutect2, varscan2
- TUBA3D | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.173); catalogued as COSV100342665; called by muse, varscan2
- YLPM1 | c.4664T>G p.L1555R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.031); catalogued as COSV99460062; called by muse, mutect2, varscan2
- ZFYVE27 | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs763939833, COSV100519312; called by muse, mutect2, varscan2
- ZNF350 | c.1558G>A p.V520M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs148220969; called by muse, mutect2, varscan2
- ZNF512B | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs370483162; called by muse, mutect2, varscan2
- ZNF580 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99553160; called by muse, mutect2, varscan2
- ZSCAN22 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 32/113 reads (28%) | catalogued as COSV100308394; called by muse, mutect2, varscan2
- CLEC7A | c.299dup p.L100Ffs*24 | Frame Shift Ins (INS) | VAF 17/100 reads (17%) | called by mutect2, varscan2
- CLIP2 | c.1842del p.K614Nfs*22 | Frame Shift Del (DEL) | VAF 98/274 reads (36%) | called by mutect2, pindel, varscan2
- DOCK3 | c.3251del p.L1084Wfs*12 | Frame Shift Del (DEL) | VAF 50/120 reads (42%) | called by mutect2, pindel, varscan2
- GPATCH2L | c.1215del p.P406Hfs*49 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel, varscan2
- MYO18A | c.2635del p.L879Cfs*60 | Frame Shift Del (DEL) | VAF 40/100 reads (40%) | called by mutect2, pindel, varscan2
- NAALADL1 | c.1315del p.V439Wfs*43 | Frame Shift Del (DEL) | VAF 25/85 reads (29%) | called by mutect2, pindel, varscan2
- RYR2 | c.6219dup p.V2074Cfs*3 | Frame Shift Ins (INS) | VAF 24/87 reads (28%) | called by mutect2, pindel, varscan2
- TRAF3 | c.247_251del p.S83Kfs*13 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- WFIKKN1 | c.191del p.K64Sfs*154 | Frame Shift Del (DEL) | VAF 34/182 reads (19%) | called by mutect2, pindel, varscan2
- ZNF549 | c.1209_1213del p.L404* (on ENST00000376233 / NM_001199295.2; = p.L391* on NM_153263.2) | Frame Shift Del (DEL) | VAF 15/93 reads (16%) | called by mutect2, pindel, varscan2
- ADAM22 | c.1818C>T p.T606= | Silent (SNP) | VAF 51/220 reads (23%) | catalogued as COSV99717307; called by muse, mutect2, varscan2
- AFG3L2 | c.1938T>G p.A646= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV99301962; called by mutect2, varscan2
- ANKRD30A | c.3544T>C p.L1182= (on ENST00000611781; = p.L1126= on NM_052997.2) | Silent (SNP) | VAF 80/251 reads (32%) | catalogued as COSV100653731; called by muse, mutect2, varscan2
- CDK15 | c.717A>G p.K239= (on ENST00000652192 / NM_001366386.2; = p.K188= on NM_139158.2) | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV99643296; called by muse, mutect2, varscan2
- CEP57L1 | c.939A>T p.S313= | Silent (SNP) | VAF 56/235 reads (24%) | catalogued as COSV100425874; called by muse, mutect2, varscan2
- ELMOD3 | c.840C>A p.V280= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as COSV55706336; called by muse, mutect2, varscan2
- FAM214A | c.1260A>G p.K420= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs750528108, COSV99957654; called by muse, mutect2, varscan2
- GANAB | c.2352G>A p.K784= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV99642064; called by muse, mutect2, varscan2
- HSD11B1 | c.867C>T p.F289= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1055894461, COSV99808207; called by muse, mutect2, varscan2
- IGF2BP1 | c.78G>A p.K26= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs1030005825, COSV99288718; called by muse, mutect2, varscan2
- KRT39 | c.1069C>T p.L357= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV100842214; called by muse, mutect2, varscan2
- LRRN4 | c.762C>T p.N254= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV101125477, COSV101125543; called by muse, mutect2, varscan2
- OBSCN | c.14322G>A p.E4774= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as COSV99480211; called by muse, mutect2, varscan2
- PLXNB1 | c.1143C>T p.H381= | Silent (SNP) | VAF 49/170 reads (29%) | catalogued as COSV99602997; called by muse, mutect2, varscan2
- POLG | c.1537T>C p.L513= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV99174856; called by muse, mutect2, varscan2
- ROBO2 | c.1866A>T p.A622= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV100167487; called by muse, mutect2, varscan2
- SEMA5B | c.573C>T p.V191= | Silent (SNP) | VAF 87/195 reads (45%) | catalogued as rs777940305, COSV99532229; called by muse, mutect2, varscan2
- SIGLEC10 | c.453C>T p.P151= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as rs139091162; called by muse, varscan2
- SLC7A14 | c.174C>T p.L58= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as COSV99200574; called by muse, mutect2, varscan2
- YLPM1 | c.4665A>G p.L1555= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs1282207778, COSV99460067; called by muse, mutect2, varscan2
- CPLANE1 | c.*3544T>C | 3'UTR (SNP) | VAF 19/90 reads (21%) | catalogued as COSV57054480; called by muse, mutect2, varscan2
- KIF1B | c.2115+7154C>A | Intron (SNP) | VAF 58/204 reads (28%) | catalogued as COSV99823587, COSV99823721; called by muse, mutect2, varscan2
